CCDI case PBCALX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/77a88e87-4c24-4ee0-8e17-c99d82ff0c94

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.0 years (2,553 days).

Biospecimens (3 samples)
- Sample 0DMIO2: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMIOT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DMIPJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
